Somatic mutation profile of tumor specimen 0DQU4Y from CCDI case PBCFBX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.9 years (5,430 days).
Specimen 0DQU4Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee299116-90d6-404b-8fd4-196ae9185eba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQU58 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/205b3cc4-d259-483e-9adc-8834a3ceea50

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT3 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 19/481 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV55608355; called by muse, mutect2
- BRDT | c.862C>T p.H288Y | Missense Mutation (SNP) | VAF 165/1008 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV62867814; called by muse, mutect2, varscan2
- CDH23 | c.3730G>A p.V1244M | Missense Mutation (SNP) | VAF 57/717 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs1478583640, COSV56478554; called by muse, mutect2
- DCAF4L1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 296/1191 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1004308327, COSV100295686; called by muse, mutect2, varscan2
- SLC26A1 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 91/478 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751574638, COSV56101453; called by muse, mutect2, varscan2
- BPTF | c.8584A>G p.T2862A | Missense Mutation (SNP) | VAF 220/1189 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARG | c.1910C>A p.A637D | Missense Mutation (SNP) | VAF 189/862 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SRPX2 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 252/501 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC5A | c.2093G>T p.S698I | Missense Mutation (SNP) | VAF 199/1093 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- ABL1 | c.3162C>T p.S1054= | Silent (SNP) | VAF 87/768 reads (11%) | catalogued as rs775473443; called by muse, mutect2, varscan2
- FKBP9 | c.730C>T p.L244= | Silent (SNP) | VAF 126/668 reads (19%) | catalogued as COSV54232418; called by muse, varscan2
- PHACTR2 | c.1461A>C p.P487= | Silent (SNP) | VAF 184/1028 reads (18%) | called by muse, mutect2, varscan2
- SETX | c.*77A>G | 3'UTR (SNP) | VAF 34/111 reads (31%) | catalogued as rs1001620356; called by muse, mutect2
- TP73 | c.-12G>A | 5'UTR (SNP) | VAF 14/424 reads (3%) | catalogued as rs1425357405; called by muse, mutect2
